Gene-level copy-number profile of tumor specimen TCGA-13-0921-01A from TCGA case TCGA-13-0921, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 72.8 years (26,606 days).
Specimen TCGA-13-0921-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.bf96a59e-7403-42f6-99b2-e56a1010cdc7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0921-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5459981b-30e1-44fe-ab55-99c36d00ec8c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 1,968; copy number 2: 21,602; copy number 3: 20,060; copy number 4: 13,247; copy number 5: 2,239; copy number 6: 11; copy number 7: 27; copy number 8: 8; copy number 9: 95; copy number 10: 109; copy number 12: 298; copy number 13: 113; copy number 21: 3; copy number 48: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0921-01A-01D-0399-01): tumor purity 0.84, ploidy 2.97, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,932 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:66,622,760–70,808,452, 42 genes, copy number 5–21: AC104440.1, RPL21P41, AC098969.2, AC098969.1, AC020655.1, KBTBD8, MIR4272, AC114401.1, SUCLG2, NDUFB4P1, SUCLG2-AS1, TAFA1, COPS8P2, AC107626.1, AC104167.1, AC096922.1, PSMC1P1, TAFA4, RNA5SP135, EOGT, AC109587.1, TMF1, MIR3136, UBA3, ARL6IP5, LMOD3, FRMD4B, RBM43P1, AC099328.1, AC099328.2, AC104445.1, MITF, RN7SL418P, SAMMSON, AC139700.1, UQCRHP4, MDFIC2, AC104633.1, AC104633.2, COX6CP6, HMGB1P36, RNU6-281P.
- chr3:126,988,594–127,537,817, 11 genes, copy number 6 (within-gene range 4–6): PLXNA1, AC112482.2, C3orf56, Y_RNA, AC112482.1, RNU6-1047P, AC133681.1, PRR20G, LINC02016, LINC01471, AC016968.1.
- chr7:46,890,625–48,108,736, 17 genes, copy number 5: AC004870.4, AC004870.2, AC004870.3, MRPL42P4, AC004870.1, AC087175.1, TNS3, LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3, C7orf57, UPP1.
- chr8:143,412,749–145,066,685, 118 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr11:28,108,248–28,527,041, 1 gene, copy number 48 (within-gene range 1–48): METTL15.
- chr11:28,287,235–36,697,867, 141 genes, copy number 13–48 (broad region; genes not listed).
- chr11:45,240,302–45,513,802, 7 genes, copy number 5 (within-gene range 3–5): SYT13, AC103681.1, LINC02696, LINC02687, AC103855.3, AC018716.2, AC018716.1.
- chr12:43,633,093–46,876,784, 46 genes, copy number 7–12: AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1, TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1, AC025253.2, NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, AC009248.3, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4.
- chr13:61,805,150–111,672,608, 547 genes, copy number 5 (broad region; genes not listed).
- chr17:50,362,967–83,095,122, 970 genes, copy number 5 (broad region; genes not listed).
- chr19:6,729,914–24,163,425, 930 genes, copy number 5–12 (broad region; genes not listed).
- chr20:52,972,358–54,070,594, 20 genes, copy number 5 (within-gene range 4–5): TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756.
- chr20:63,009,383–63,085,071, 1 gene, copy number 5 (within-gene range 3–5): LINC01749.
- chr20:63,038,011–64,313,132, 81 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 942. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
